Surgical pathology report (de-identified scan), TCGA case TCGA-2H-A9GR, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Erasmus MC, specimen TCGA-2H-A9GR-01A (Primary Tumor).

Pathology Report

Coded sample ID:

Date of tumor procurement:

Date of report:

Histologic diagnosis: moderate differentiated adenocarcinoma in Barrett-epithelium

Anatomic site with laterality: distal esophagus

Tumor size: diameter 3 cm

Lymph node status: 3 negative lymph nodes

Any comments or amendments: irradical resection

ICD-O-3
Adenocarcinoma NOS 8140/3
Site: Esophagus, distal third C15.5
JW 1/29/14

Source: NCI Genomic Data Commons file 262f728a-e403-48ab-a497-4375216862a8 (TCGA-2H-A9GR.295F593F-2B4C-45A9-82B5-E6C120934645.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).